Somatic mutation profile of tumor specimen MP2PRT-PATHJM-TBP1-A (aliquot MP2PRT-PATHJM-TBP1-A-1-0-D-A81Y-36) from MP2PRT case MP2PRT-PATHJM, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.7 years (623 days).
Specimen MP2PRT-PATHJM-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7838e638-9da2-46d9-9a57-27828ff89a43.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATHJM-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATHJM-NB1-A-1-0-D-A81Y-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1633ed08-656d-4de9-840c-db566044ce44

The open-access MAF lists 7 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 6, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAP1A | c.7942C>T p.R2648C | Missense Mutation (SNP) | VAF 41/674 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.301); catalogued as rs758664345, COSV100288167; called by muse, mutect2
- TEX13A | c.1045C>A p.P349T | Missense Mutation (SNP) | VAF 39/824 reads (5%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as COSV61146934; called by muse, mutect2
- TFAP4 | c.148C>G p.R50G | Missense Mutation (SNP) | VAF 26/494 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52597307; called by muse, mutect2
- BSN | c.9212C>T p.T3071I | Missense Mutation (SNP) | VAF 33/768 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.109); called by muse, mutect2
- RNF2 | c.266C>T p.T89I | Missense Mutation (SNP) | VAF 22/326 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SPATA31E1 | c.1882T>C p.W628R | Missense Mutation (SNP) | VAF 36/762 reads (5%) | SIFT tolerated (0.84); PolyPhen benign (0); called by muse, mutect2
- PIK3CD | c.1404C>T p.A468= | Silent (SNP) | VAF 46/759 reads (6%) | catalogued as rs771683726; ClinVar: likely benign; called by muse, mutect2
